TCGA case TCGA-WY-A85B — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cb041720-0efa-4eb6-a9a5-b6e138bb1a99

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 24 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 24.1 years (8,817 days); Year of diagnosis: 2010; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,393 days (3.8 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,003 days (2.7 years); Disease response: Tumor Free.
- Days to follow up: 1,393 days (3.8 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Seizure / Sensory Changes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WY-A85B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 420 mg.
  Slide TCGA-WY-A85B-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WY-A85B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WY-A85B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Temporal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: Yes; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant medication: Yes; Family history brain tumor: No; Inherited genetic syndrome indicator: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,393 days; disease-specific survival: no event (censored), 1,393 days; disease-free interval: no event (censored), 1,393 days; progression-free interval: no event (censored), 1,393 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WY-A85B-01A-11D-A36N-01): tumor purity 0.87, ploidy 2, whole-genome doublings 0.
